Somatic mutation profile of tumor specimen MP2PRT-PATCNN-TMP1-A (aliquot MP2PRT-PATCNN-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PATCNN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,031 days).
Specimen MP2PRT-PATCNN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 567388c3-3fd3-40d5-b204-22b5d8addf46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCNN-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCNN-NM1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/354e2fc7-2b39-4e82-ac49-77d082216a28

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 1, 3'Flank 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.3302G>C p.G1101A | Missense Mutation (SNP) | VAF 27/480 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as COSV52469833; called by muse, mutect2
- AL592490.1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs751419926; called by muse, mutect2, varscan2
- ALG10 | c.495G>C p.L165F | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); catalogued as COSV56792327; called by muse, mutect2, varscan2
- COL1A2 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 62/289 reads (21%) | catalogued as COSV51954553; called by muse, mutect2, varscan2
- FBXL12 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 134/417 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.547); catalogued as rs1354760787, COSV56113823; called by muse, mutect2, varscan2
- LAMC3 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 107/312 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1011715171; called by muse, mutect2, varscan2
- NIM1K | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 112/351 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs776484045, COSV58146815; called by muse, mutect2, varscan2
- SLC2A6 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 39/608 reads (6%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as rs781846045; called by muse, mutect2
- ARHGAP31 | c.3280G>C p.E1094Q | Missense Mutation (SNP) | VAF 130/432 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- CRPPA | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 46/730 reads (6%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.487); called by muse, mutect2
- DNAJC11 | c.50C>G p.S17W | Missense Mutation (SNP) | VAF 118/444 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- IGLV4-60 | c.355_362delinsCTTCCGC p.N119Lfs*? | Frame Shift Del (DEL) | VAF 33/105 reads (31%) | called by pindel, varscan2*
- LCA5 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MADD | c.4360G>A p.D1454N | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NSD2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NUDT19 | c.885C>G p.I295M | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NWD2 | c.1552C>A p.Q518K | Missense Mutation (SNP) | VAF 108/308 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- PKD1L2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC52A3 | c.533G>T p.S178I | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ST3GAL6 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBB2B | c.1010A>C p.N337T | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZBTB7A | c.1067_1068insAGAC p.F356Lfs*185 | Frame Shift Ins (INS) | VAF 94/410 reads (23%) | called by mutect2, pindel, varscan2
- COL17A1 | c.3750G>C p.L1250= | Silent (SNP) | VAF 77/241 reads (32%) | catalogued as rs1456917432; called by muse, mutect2, varscan2
- MPL | c.84C>T p.V28= | Silent (SNP) | VAF 95/291 reads (33%) | called by muse, mutect2, varscan2
- PDE4D | c.1926C>T p.F642= (on ENST00000340635 / NM_001104631.2; = p.F506= on NM_006203.4) | Silent (SNP) | VAF 28/393 reads (7%) | called by muse, mutect2
- SHANK3 | c.3150C>A p.L1050= | Silent (SNP) | VAF 123/399 reads (31%) | catalogued as rs765858091; called by muse, mutect2, varscan2
- TSHZ1 | c.2292G>A p.V764= (on ENST00000580243 / NM_001308210.2; = p.V719= on NM_005786.6) | Silent (SNP) | VAF 104/393 reads (26%) | called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506995 ins AGGGGGGTA | 3'Flank (INS) | VAF 28/79 reads (35%) | called by pindel, varscan2
